Somatic mutation profile of tumor specimen TCGA-UF-A7JH-01A (aliquot TCGA-UF-A7JH-01A-21D-A34J-08) from TCGA case TCGA-UF-A7JH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 59.0 years (21,558 days).
Specimen TCGA-UF-A7JH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7904cf38-238f-4f1a-b165-1e947cce37c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JH-10A (Blood Derived Normal), aliquot TCGA-UF-A7JH-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d868d197-aa59-4bf3-a7dc-5d0ac699d2e6

The open-access MAF lists 85 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 21, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, RNA 2, Intron 2, Splice Region 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.5734C>T p.R1912* (on ENST00000303395 / NM_001202435.3; = p.R1901* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/113 reads (50%) | catalogued as rs77216276, CD114895, CM044053, COSV57661348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1213719069, COSV100216438; called by muse, mutect2, varscan2
- ANAPC4 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV100193736; called by muse, mutect2, varscan2
- ANKAR | c.3205A>T p.T1069S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.289); catalogued as COSV99853787; called by muse, mutect2, varscan2
- ANKFY1 | c.2737G>A p.A913T (on ENST00000341657 / NM_001330063.2; = p.A914T on NM_016376.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261557692, COSV100492162; called by muse, mutect2
- CACNA1C | c.3156G>A p.K1052= | Splice Region (SNP) | VAF 49/99 reads (49%) | catalogued as COSV100214383; called by muse, mutect2, varscan2
- CCT8L2 | c.1161T>A p.S387R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV63463688; called by muse, mutect2, varscan2
- CDRT15 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs371777451; called by muse, mutect2, varscan2
- CFTR | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as CM022335, COSV99133658; called by muse, mutect2, varscan2
- CHEK1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs756054805, COSV54023103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.7534G>T p.A2512S | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV101483729; called by muse, mutect2, varscan2
- D2HGDH | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs764487647, COSV100344058; called by muse, mutect2, varscan2
- DGKG | c.1424+2T>A p.X475_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99402176; called by muse, mutect2, varscan2
- DPYD | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as rs750687600, COSV100928368; called by muse, mutect2, varscan2
- EMSY | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595256; called by muse, mutect2, varscan2
- ESRRG | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 62/141 reads (44%) | catalogued as COSV100752155; called by muse, mutect2, varscan2
- ETAA1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs928656658, COSV99712523; called by muse, mutect2, varscan2
- FAM160A2 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776133021, COSV99791609; called by muse, mutect2, varscan2
- FAM47A | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100649666; called by muse, mutect2, varscan2
- FOXF2 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99452867; called by muse, mutect2
- GPR101 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99981204; called by muse, mutect2, varscan2
- HECTD4 | c.3544C>G p.Q1182E | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100295754, COSV61180806; called by muse, mutect2, varscan2
- INTS4 | c.761A>T p.Q254L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV101417107; called by muse, mutect2, varscan2
- KEL | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as COSV100786815, COSV99051238; called by muse, mutect2, varscan2
- LCT | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs1459165220, COSV99928333; called by muse, mutect2, varscan2
- MMP11 | c.615G>A p.Q205= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as rs1276541227, COSV99302974, COSV99303202; called by muse, mutect2, varscan2
- MNT | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99437892; called by muse, mutect2
- MRC1 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs200635754, COSV99519558; called by muse, mutect2, varscan2
- MUC2 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated, low confidence (0.07); catalogued as rs781571861; called by muse, mutect2, varscan2
- NCK2 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.602); catalogued as COSV99255040; called by muse, varscan2
- OPRM1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs201516315, COSV57679855, COSV57679871; called by muse, mutect2, varscan2
- OR4K2 | c.792C>A p.S264R | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100063951; called by muse, mutect2, varscan2
- PHRF1 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV99199350; called by muse, mutect2, varscan2
- PKD2L1 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs760940072, COSV100559242; called by muse, mutect2, varscan2
- PLA2G7 | c.794A>G p.E265G | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV51258355, COSV99221047; called by muse, mutect2, varscan2
- PRPF38B | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100898165; called by muse, mutect2
- PTBP3 | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100533935; called by muse, mutect2, varscan2
- PTPRB | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 131/205 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- RBM33 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs758201933, COSV100265094; called by muse, mutect2, varscan2
- SCN3A | c.4257G>A p.W1419* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as rs1553518168, COSV99325388; called by muse, mutect2, varscan2
- SCN3A | c.4256G>C p.W1419S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325390, COSV99327020; called by muse, mutect2, varscan2
- SLC20A1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99733817; called by muse, mutect2, varscan2
- SLC25A46 | c.723A>C p.K241N | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100582483; called by muse, mutect2, varscan2
- SPTB | c.5317G>A p.D1773N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101071883; called by muse, mutect2, varscan2
- TMEM140 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99313071; called by mutect2, varscan2
- TP53 | c.839_842dup p.D281Efs*26 | Frame Shift Ins (INS) | VAF 18/27 reads (67%) | catalogued as COSV52873430, COSV52898385, COSV53426350; called by mutect2, pindel
- TRAPPC8 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as COSV99350401; called by muse, mutect2, varscan2
- UBQLN4 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as COSV100849052; called by muse, mutect2, varscan2
- UNC13C | c.4541C>T p.S1514L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99510158; called by muse, mutect2, varscan2
- USF1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.28); catalogued as rs770972784, COSV57039251; called by muse, mutect2, varscan2
- USP36 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 107/155 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs757533435, COSV61752139; called by muse, mutect2, varscan2
- UTRN | c.5173C>A p.L1725I | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV100839396; called by muse, mutect2, varscan2
- VN1R2 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV100447732, COSV59038638; called by muse, mutect2, varscan2
- ZRANB2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54671243; called by muse, mutect2, varscan2
- GAS2 | c.587del p.K196Rfs*11 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- MMP25 | c.995_998del p.F332Sfs*35 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- SLC22A10 | c.1599-1del p.X533_splice | Splice Site (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- STRN4 | c.2256_2257del p.V753Mfs*23 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel*
- WSB2 | c.944+1dup p.X315_splice | Splice Site (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- ACSM1 | c.672C>T p.F224= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV54634982; called by muse, mutect2, varscan2
- BCL2L12 | c.978C>T p.P326= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs759969547, COSV99880953; called by muse, mutect2, varscan2
- BTBD6 | c.358C>T p.L120= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs747048900, COSV100526729; called by muse, mutect2, varscan2
- CCNA1 | c.435G>A p.G145= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as COSV99714187; called by muse, mutect2, varscan2
- CLIP3 | c.1629G>A p.A543= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs751326856, COSV99430751; called by muse, mutect2, varscan2
- CNTN1 | c.3033C>T p.G1011= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1485133432, COSV100750799; called by muse, mutect2, varscan2
- FURIN | c.447C>G p.V149= | Silent (SNP) | VAF 68/103 reads (66%) | catalogued as COSV99184603; called by muse, mutect2, varscan2
- GPR148 | c.786C>A p.T262= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs1284724669, COSV59308839; called by muse, mutect2, varscan2
- KCNJ3 | c.1248C>A p.L416= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV54534573; called by muse, mutect2, varscan2
- NECTIN4 | c.555G>T p.T185= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1000838954, COSV100919788, COSV63513667; called by muse, mutect2, varscan2
- NLRP12 | c.1638C>T p.T546= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs762831332, COSV100145075, COSV60743457; called by muse, mutect2, varscan2
- OR4K17 | c.438G>T p.V146= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as COSV59647810; called by muse, mutect2, varscan2
- PRPH | c.1203G>A p.E401= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99141920; called by muse, mutect2, varscan2
- RHOT2 | c.1029C>G p.P343= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs1024298416, COSV99552508; called by muse, mutect2, varscan2
- RYR3 | c.9711C>T p.A3237= (on ENST00000389232; = p.A3238= on NM_001036.6) | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as rs904778183, COSV66777719; called by muse, mutect2
- SIM2 | c.1558C>T p.L520= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs199788000, COSV51773697; called by muse, mutect2
- SLC18A3 | c.1527C>T p.G509= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100339564; called by muse, mutect2, varscan2
- SLC27A6 | c.234C>T p.D78= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as COSV99321981; called by muse, mutect2, varscan2
- TOX2 | c.1023G>A p.S341= (on ENST00000358131 / NM_001098798.2; = p.S317= on NM_032883.3) | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs1046792403, COSV100363190; called by muse, mutect2, varscan2
- TSPEAR | c.882G>A p.L294= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs782296232, COSV100551438; called by muse, mutect2, varscan2
- ZNF440 | c.1110T>C p.C370= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1442669699, COSV100407315; called by muse, mutect2
- AP000769.3 | chr11:65501434 G>A | 5'Flank (SNP) | VAF 7/24 reads (29%) | catalogued as rs1160775938; called by muse, mutect2
- ASPH | c.323-11746A>G | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100727325, COSV62861135; called by muse, mutect2, varscan2
- LOXL2 | c.-83-17520C>T | Intron (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100652469; called by muse, mutect2, varscan2
- SERPINA13P | n.746T>C | RNA (SNP) | VAF 54/136 reads (40%) | catalogued as rs1305648077; called by muse, mutect2, varscan2
- SSPOP | n.10150G>A | RNA (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100946917; called by muse, mutect2, varscan2
